Somatic mutation profile of tumor specimen ALCH-B6Y0-TTP1-A (aliquot ALCH-B6Y0-TTP1-A-1-0-D-A95P-47) from ALCHEMIST case ALCH-B6Y0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.1 years (24,153 days).
Specimen ALCH-B6Y0-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ffc74aa-80bc-4eae-a0d7-6fa16be4d9d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B6Y0-NB1-A (Peripheral Whole Blood; tissue type Normal), aliquot ALCH-B6Y0-NB1-A-1-0-D-A95P-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a0ba5f8-4785-4777-a77f-887e1adfd737

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, In Frame Del 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNA4 | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.435); catalogued as rs1270318199, COSV100068784, COSV60254907; called by muse, mutect2
- PDE3A | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs143792143; called by muse, mutect2
- RNF223 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.369); catalogued as rs951044032; called by muse, mutect2, varscan2
- SFTPB | c.869_871del p.G290del | In Frame Del (DEL) | VAF 6/52 reads (12%) | catalogued as rs944488327; called by mutect2, pindel, varscan2
- ARFGEF2 | c.500A>G p.Y167C | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- GGCX | c.387G>A p.M129I | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- KRTAP13-1 | c.13T>A p.C5S | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); called by muse, mutect2
- MIEF2 | c.703del p.R235Vfs*44 | Frame Shift Del (DEL) | VAF 3/20 reads (15%) | called by pindel, varscan2
- RBMS1 | c.191T>G p.L64R | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TAF4 | c.1903G>T p.E635* | Nonsense Mutation (SNP) | VAF 14/74 reads (19%) | called by muse, varscan2
- MYCBP2 | c.12489A>G p.E4163= (on ENST00000357337; = p.E4201= on NM_015057.5) | Silent (SNP) | VAF 9/176 reads (5%) | called by muse, mutect2
- TANC1 | c.5424C>T p.C1808= | Silent (SNP) | VAF 19/169 reads (11%) | called by muse, mutect2
